Somatic mutation profile of tumor specimen TARGET-10-PAPEJM-09A (aliquot TARGET-10-PAPEJM-09A-01D) from TARGET case TARGET-10-PAPEJM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,344 days).
Specimen TARGET-10-PAPEJM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97563363-b398-4ff9-8b0a-f3d5e5f7f656.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEJM-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEJM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5555604e-b7d0-42f9-9aa6-f4142e78c741

The open-access MAF lists 34 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 8, Silent 3, 3'Flank 2, 5'Flank 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGGF1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs909784085; called by muse, mutect2
- C6orf58 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV100314669; called by muse, mutect2
- CLDN10 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.363); catalogued as COSV65296426; called by muse, mutect2, varscan2
- CRACD | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as rs373181510; called by muse, mutect2, varscan2
- DSG4 | c.2977G>A p.G993S | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs1412936496; called by muse, mutect2, varscan2
- IFNE | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1423733096, COSV100438850; called by muse, mutect2, varscan2
- OR2A12 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68821111, COSV99065255; called by muse, mutect2, varscan2
- SERPINI2 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV52985475; called by muse, mutect2, varscan2
- TMEM130 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs149015420; called by mutect2, varscan2
- YTHDF1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64832807; called by muse, mutect2
- ABCC9 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HTRA1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- IGHV3-7 | chr14:106062145 TGTGTCTCTCGCACAGTAAT>CTCTGAGGG | Missense Mutation (DEL) | VAF 30/61 reads (49%) | called by pindel, varscan2*
- LCOR | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NFKBIL1 | c.957_963delinsTGTTCCT p.R320_G321delinsVP | Missense Mutation (ONP) | VAF 20/75 reads (27%) | called by pindel, varscan2*
- OFD1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PPP1R3F | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.045); called by muse, mutect2
- SNRPC | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSBG2 | c.112C>T p.L38= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- H4C12 | c.12C>T p.R4= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs748307352; called by muse, mutect2, varscan2
- OR2H1 | c.234G>A p.Q78= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- BSG | c.416-381C>T | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- BSG | c.416-205C>T | Intron (SNP) | VAF 6/44 reads (14%) | catalogued as rs1242371126; called by mutect2, varscan2
- DNAI1 | c.262-1302G>A | Intron (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- ENOSF1 | chr18:673068 C>T | 3'Flank (SNP) | VAF 8/94 reads (9%) | catalogued as COSV51895435; called by muse, mutect2
- HDGF | chr1:156752390 C>G | 5'Flank (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656181 G>C | 3'Flank (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- LRP8 | c.2435-168A>G | Intron (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- NRBP1 | c.566+94C>G | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- POFUT2 | c.1136+74G>A | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- PSMB9 | c.*100G>A | 3'UTR (SNP) | VAF 13/42 reads (31%) | catalogued as rs1384979695; called by muse, mutect2
- STXBP2 | c.1246+141C>G | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2
- TBC1D20 | c.627-56G>C | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
